Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96D, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96D-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

Pathology Report-Summary:

Material:

tumor: 16.0 x 10.0 x 9.0 cm

focal invasion through capsule into fat tissue

Diagnosis:

Type A/B-Thymoma

pT2, pNx, pMx

Masaoka: II.2

ICD-O-3
Thymoma, type AB
malignant (8582)3
Site Anterior mediastinum
C38.1
Q54/7/14

Immunohistochemistry

epithelial cells positive for: CK5/6
medium membrane staining for EGFR

epithelial cells negative for: CD5, CD117, CD1a, CD99, CD20

CD1a, CD99-positive immature T-lymphocytes
sparsely CD20-positive B-lymphocytes

Source: NCI Genomic Data Commons file b7b3e1b4-e1d0-4c89-a91d-d629d18c491c (TCGA-ZB-A96D.7B06FFA1-E992-438A-9BE8-E5E7D7E203FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).